Somatic mutation profile of tumor specimen TCGA-37-3783-01A (aliquot TCGA-37-3783-01A-01D-1267-08) from TCGA case TCGA-37-3783, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 51.3 years (18,728 days).
Specimen TCGA-37-3783-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 738fe015-8917-4810-809b-0415f2c512c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-37-3783-10A (Blood Derived Normal), aliquot TCGA-37-3783-10A-01D-1267-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b562d9f2-5fb2-4eac-8524-a34bd3c82d93

The open-access MAF lists 404 somatic variants for this specimen: 289 protein-altering or splice-affecting, 99 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 255, Silent 99, Nonsense Mutation 22, Intron 7, Frame Shift Del 7, Frame Shift Ins 3, RNA 3, 5'Flank 3, 5'UTR 2, Splice Site 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4241A>G p.Y1414C | Missense Mutation (SNP) | VAF 14/76 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54325155; called by muse, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 53/166 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 13/57 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ABCA10 | c.4406C>G p.S1469C | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV52227462; called by muse, mutect2
- ABCB1 | c.893C>G p.S298C | Missense Mutation (SNP) | VAF 35/310 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV55959158, COSV99713297; called by muse, mutect2, varscan2
- ACTN3 | c.1844A>G p.N615S | Missense Mutation (SNP) | VAF 61/338 reads (18%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs1165208376, COSV59750070; called by muse, mutect2, varscan2
- ADAM29 | c.2375C>G p.P792R | Missense Mutation (SNP) | VAF 42/264 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.053); catalogued as rs1216620594, COSV63666403; called by muse, mutect2, varscan2
- ADAMTS12 | c.4559C>A p.P1520H | Missense Mutation (SNP) | VAF 74/237 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61273027; called by muse, mutect2, varscan2
- ADGRF4 | c.741C>G p.I247M | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as COSV51955629; called by muse, mutect2, varscan2
- ADGRF4 | c.1307C>A p.S436* | Nonsense Mutation (SNP) | VAF 63/358 reads (18%) | catalogued as COSV51955644, COSV99348560; called by muse, mutect2, varscan2
- ADGRF4 | c.1753C>G p.Q585E | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.627); catalogued as COSV51955701; called by muse, varscan2
- ADGRF5 | c.1495T>A p.Y499N | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51938111; called by muse, mutect2, varscan2
- ADGRL2 | c.790A>T p.I264F | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54680587; called by muse, mutect2, varscan2
- ADM5 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.015); catalogued as COSV54920185; called by muse, mutect2
- AKAP9 | c.9181G>C p.E3061Q (on ENST00000359028; = p.E3037Q on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/644 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62354200; called by muse, mutect2, varscan2
- AL592490.1 | c.2654C>G p.S885C | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.466); catalogued as COSV69427293; called by muse, mutect2, varscan2
- AMMECR1L | c.536G>T p.R179L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55761519; called by muse, mutect2, varscan2
- ANGPTL4 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 123/683 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); catalogued as COSV56845404; called by muse, mutect2, varscan2
- ANKRD17 | c.2695C>A p.Q899K | Missense Mutation (SNP) | VAF 35/261 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV58225489; called by muse, mutect2, varscan2
- ANO4 | c.1960A>C p.M654L (on ENST00000392977 / NM_001286615.2; = p.M619L on NM_178826.4) | Missense Mutation (SNP) | VAF 37/307 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV54607089; called by muse, mutect2, varscan2
- ASAP1 | c.1175G>C p.R392T | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63052639; called by muse, mutect2, varscan2
- ATXN3L | c.977G>C p.S326T | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as COSV66076099; called by muse, mutect2, varscan2
- BBS7 | c.441C>G p.I147M | Missense Mutation (SNP) | VAF 44/272 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52658581; called by muse, mutect2, varscan2
- BMP2K | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as COSV58597880; called by muse, mutect2, varscan2
- BOP1 | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 36/252 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56640067; called by muse, mutect2, varscan2
- BRAF | c.284G>C p.R95T | Missense Mutation (SNP) | VAF 36/235 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1554409395, COSV56306760; ClinVar: benign; called by muse, mutect2, varscan2
- BRD8 | c.1234G>C p.D412H (on ENST00000254900 / NM_139199.2; = p.D485H on NM_006696.4) | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50162737; called by muse, mutect2, varscan2
- BRINP3 | c.1723C>A p.P575T | Missense Mutation (SNP) | VAF 40/404 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV66529969, COSV66535162; called by muse, mutect2, varscan2
- BTG3 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.069); catalogued as COSV60287150; called by muse, mutect2, varscan2
- BUD13 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 40/313 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV52769894; called by muse, mutect2, varscan2
- C11orf16 | c.402G>C p.Q134H | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV58168636; called by muse, varscan2
- C1QB | c.589G>T p.D197Y | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59245814; called by muse, mutect2, varscan2
- CACNG7 | c.53C>A p.A18E | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as rs1194057520, COSV55813346, COSV55816386; called by muse, mutect2, varscan2
- CALCOCO1 | c.1339A>G p.N447D | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as rs1161144613, COSV50418915; called by muse, mutect2, varscan2
- CCDC82 | c.104C>G p.S35* | Nonsense Mutation (SNP) | VAF 14/76 reads (18%) | catalogued as COSV53594839; called by muse, mutect2, varscan2
- CDC20B | c.1160G>A p.G387D | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs954474932, COSV57055411; called by muse, mutect2, varscan2
- CDH2 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 61/314 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs963079228, COSV52291141; called by muse, mutect2, varscan2
- CDH8 | c.1216C>G p.L406V | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54876445; called by muse, mutect2, varscan2
- CDK13 | c.1949C>T p.P650L | Missense Mutation (SNP) | VAF 44/332 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV51704327; called by muse, mutect2, varscan2
- CELF1 | c.146G>C p.R49T | Missense Mutation (SNP) | VAF 54/387 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV60114342; called by muse, mutect2, varscan2
- CENPI | c.1033C>G p.Q345E | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV54505125; called by muse, mutect2, varscan2
- CEP192 | c.3772G>T p.A1258S | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV58068558; called by muse, mutect2, varscan2
- CIB4 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 63/418 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV56602776, COSV56602947; called by muse, mutect2, varscan2
- CKAP5 | c.1798C>T p.L600F | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.358); catalogued as COSV56372016; called by muse, mutect2, varscan2
- CNTN1 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61643524; called by muse, mutect2, varscan2
- CNTN1 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.052); catalogued as COSV61643529; called by muse, mutect2, varscan2
- CNTN6 | c.896C>G p.A299G | Missense Mutation (SNP) | VAF 39/222 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100610269, COSV63183518; called by muse, mutect2, varscan2
- CNTNAP2 | c.3650C>T p.S1217L | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.288); catalogued as rs1409978017, COSV62232872; called by muse, mutect2, varscan2
- CNTNAP5 | c.3541C>A p.R1181S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.995); catalogued as rs969802074, COSV101443060, COSV70502340; called by muse, mutect2, varscan2
- CNTRL | c.5050C>A p.L1684I | Missense Mutation (SNP) | VAF 61/160 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs752381692, COSV53051360; called by muse, mutect2, varscan2
- COL27A1 | c.3524C>G p.T1175S | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as COSV61929542; called by muse, mutect2, varscan2
- CORO1B | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as COSV58171470; called by muse, mutect2, varscan2
- CPXCR1 | c.314C>A p.P105H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.726); catalogued as COSV52163972; called by muse, mutect2, varscan2
- CRISP1 | c.312T>A p.H104Q | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.213); catalogued as rs751048125, COSV59994770; called by muse, mutect2, varscan2
- CRLF3 | c.1309T>C p.W437R | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV60836786; called by muse, mutect2, varscan2
- CSMD1 | c.3661C>T p.P1221S (on ENST00000520002; = p.P1220S on NM_033225.6) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as COSV59360927; called by muse, mutect2, varscan2
- CSMD3 | c.2905del p.Q969Kfs*37 (on ENST00000297405 / NM_001363185.1; = p.Q865Kfs*37 on NM_052900.3) | Frame Shift Del (DEL) | VAF 11/72 reads (15%) | catalogued as COSV99846166; called by mutect2, pindel, varscan2
- CUBN | c.10526C>G p.S3509C | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs1422497587, COSV64723318; called by muse, mutect2, varscan2
- CWF19L2 | c.1503C>G p.I501M | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV56511519, COSV56517412; called by muse, mutect2, varscan2
- CYP1A1 | c.1281_1282insAGGT p.L428Rfs*4 | Frame Shift Ins (INS) | VAF 37/286 reads (13%) | catalogued as COSV101122364; called by mutect2, pindel, varscan2
- DDR1 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 78/628 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61323597; called by muse, varscan2
- DENND5B | c.3808A>G p.K1270E | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV60906294; called by muse, mutect2, varscan2
- DIXDC1 | c.1399G>T p.V467F (on ENST00000440460 / NM_001037954.4; = p.V256F on NM_033425.4) | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.556); catalogued as COSV59462947; called by muse, mutect2, varscan2
- DNAH6 | c.1305G>C p.M435I | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV52875785; called by muse, mutect2, varscan2
- DNM3 | c.300G>T p.E100D | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV62463909, COSV62469765; called by muse, mutect2
- DOCK10 | c.1424C>G p.S475* | Nonsense Mutation (SNP) | VAF 40/466 reads (9%) | catalogued as COSV51423324; called by muse, mutect2
- DPP8 | c.1252G>A p.D418N (on ENST00000341861 / NM_001320875.2; = p.D402N on NM_017743.6) | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.036); catalogued as COSV55681730; called by muse, mutect2, varscan2
- DTNA | c.2122G>C p.E708Q | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.545); catalogued as COSV52018341; called by muse, mutect2, varscan2
- DYNC2H1 | c.1640C>T p.S547F | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as COSV62102298; called by muse, mutect2, varscan2
- EMC7 | c.525A>G p.I175M | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1311744874, COSV56628707; called by muse, mutect2, varscan2
- EP300 | c.769T>G p.Y257D | Missense Mutation (SNP) | VAF 34/213 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV54340925; called by muse, mutect2, varscan2
- EPSTI1 | c.698G>C p.S233T (on ENST00000398762 / NM_001330543.2; = p.S222T on NM_033255.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/242 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV58047704; called by muse, mutect2, varscan2
- ERICH3 | c.1518G>C p.E506D | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as rs745497573, COSV100443276, COSV58614296; called by muse, mutect2, varscan2
- ERO1B | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 20/153 reads (13%) | catalogued as rs770855048, COSV59243397; called by muse, mutect2, varscan2
- ESR1 | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV52798296; called by muse, mutect2, varscan2
- EYS | c.640C>G p.L214V | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV60995992; called by muse, mutect2, varscan2
- FAM171A1 | c.272C>G p.S91W | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV65318561; called by muse, mutect2, varscan2
- FLG | c.11953G>C p.D3985H | Missense Mutation (SNP) | VAF 54/313 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV64241805, COSV64245865; called by muse, mutect2, varscan2
- FLG | c.6154G>T p.E2052* | Nonsense Mutation (SNP) | VAF 183/1318 reads (14%) | catalogued as COSV100910572, COSV64245868; called by muse, mutect2, varscan2
- FOXD4L4 | c.623A>G p.Q208R | Missense Mutation (SNP) | VAF 53/656 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as rs1209934197; called by muse, mutect2, varscan2
- FPGS | c.544A>G p.T182A | Missense Mutation (SNP) | VAF 136/364 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as COSV64676093; called by muse, varscan2
- FSHR | c.1888A>G p.T630A | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs779291542, COSV58624572; called by muse, mutect2, varscan2
- GCFC2 | c.1570T>C p.W524R | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58082667; called by muse, mutect2, varscan2
- GCM1 | c.1307G>A p.R436K | Missense Mutation (SNP) | VAF 60/360 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV52523380; called by muse, mutect2
- GCM1 | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV52523387; called by muse, mutect2, varscan2
- GDAP1L1 | c.1078T>C p.W360R | Missense Mutation (SNP) | VAF 39/236 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV61158412; called by muse, mutect2, varscan2
- GLUD1 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 24/394 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV53280422; called by muse, mutect2
- GPAM | c.1238A>T p.Q413L | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as COSV62082126; called by muse, mutect2, varscan2
- GPAT2 | c.1592A>G p.Q531R | Missense Mutation (SNP) | VAF 49/251 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758171102, COSV64003778; called by muse, mutect2, varscan2
- GPATCH2 | c.967G>C p.E323Q | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV65128243; called by muse, mutect2, varscan2
- GRIA4 | c.410C>A p.S137* | Nonsense Mutation (SNP) | VAF 30/144 reads (21%) | catalogued as COSV56912117; called by muse, mutect2, varscan2
- GRIN2C | c.2384C>T p.S795L | Missense Mutation (SNP) | VAF 60/512 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV53116557; called by muse, mutect2, varscan2
- GRIN3A | c.1361C>G p.S454C | Missense Mutation (SNP) | VAF 94/332 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.662); catalogued as COSV62454628, COSV62456793, COSV62456870; called by muse, mutect2, varscan2
- H3C2 | c.282G>T p.Q94H | Missense Mutation (SNP) | VAF 25/197 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV52519485; called by muse, mutect2, varscan2
- HAO1 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 60/228 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV66493325; called by muse, mutect2, varscan2
- HEATR1 | c.4509G>C p.E1503D | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs748116286, COSV63982507; called by muse, mutect2, varscan2
- HMCN1 | c.16478G>C p.R5493T | Missense Mutation (SNP) | VAF 39/305 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54895074; called by muse, mutect2, varscan2
- HNRNPU | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.389); catalogued as COSV51693156; called by muse, mutect2, varscan2
- HPDL | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 84/379 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100588029, COSV58344766; called by muse, mutect2, varscan2
- HRNR | c.2488C>T p.Q830* | Nonsense Mutation (SNP) | VAF 35/165 reads (21%) | catalogued as COSV64261102; called by muse, mutect2, varscan2
- HTR5A | c.82G>C p.D28H | Missense Mutation (SNP) | VAF 130/285 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.387); catalogued as COSV55282760, COSV55286022; called by muse, mutect2, varscan2
- IFNA7 | c.527C>G p.S176C | Missense Mutation (SNP) | VAF 74/474 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV53331935; called by muse, mutect2, varscan2
- IGKV2D-29 | c.179G>T p.W60L | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as rs1241311912, COSV101534394; called by muse, mutect2, varscan2
- IMMT | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV54488916; called by muse, varscan2
- INPP5A | c.910G>C p.E304Q | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV61250558, COSV61251754; called by muse, mutect2, varscan2
- IQGAP3 | c.3338G>A p.R1113K | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.987); catalogued as COSV63253646; called by muse, mutect2
- ISOC1 | c.505C>G p.Q169E | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.023); catalogued as COSV51492533; called by muse, mutect2
- ITGA8 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.419); catalogued as rs368735214; called by muse, mutect2, varscan2
- ITGB4 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0.314); catalogued as COSV52330556; called by muse, mutect2
- ITIH6 | c.2446C>T p.Q816* | Nonsense Mutation (SNP) | VAF 56/142 reads (39%) | catalogued as COSV54492592; called by muse, mutect2, varscan2
- ITPR2 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV67274066; called by muse, mutect2, varscan2
- ITPR3 | c.571G>T p.G191W | Missense Mutation (SNP) | VAF 34/326 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65413285, COSV65415210; called by muse, mutect2, varscan2
- JAK3 | c.1181C>T p.S394L | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.325); catalogued as COSV71686985; called by muse, mutect2, varscan2
- JARID2 | c.3527G>A p.R1176Q | Missense Mutation (SNP) | VAF 32/261 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs367941514; called by muse, mutect2, varscan2
- JUN | c.792C>G p.I264M | Missense Mutation (SNP) | VAF 77/310 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV64664794; called by muse, mutect2, varscan2
- KANK4 | c.2719G>A p.D907N | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs752600367, COSV58093371; called by muse, mutect2, varscan2
- KCND2 | c.98A>G p.Q33R | Missense Mutation (SNP) | VAF 301/776 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV58596156; called by muse, mutect2, varscan2
- KCNH7 | c.2905G>A p.E969K | Missense Mutation (SNP) | VAF 45/290 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.057); catalogued as COSV59807724; called by muse, mutect2, varscan2
- KIF1B | c.5080G>C p.E1694Q (on ENST00000377086 / NM_001365952.1; = p.E1648Q on NM_015074.3) | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0.031); catalogued as COSV55813288; called by muse, mutect2
- KIF21B | c.1096C>T p.R366W | Missense Mutation (SNP) | VAF 30/275 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1250955515, COSV59763268; called by muse, mutect2, varscan2
- KLF11 | c.1218C>G p.F406L | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59940187, COSV59941253; called by muse, mutect2, varscan2
- LAMB2 | c.3787G>C p.E1263Q | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.122); catalogued as COSV59736386; called by muse, mutect2, varscan2
- LEMD3 | c.1404C>A p.F468L | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV57652651; called by muse, mutect2, varscan2
- LMBRD1 | c.1519C>T p.H507Y (on ENST00000649011; = p.H485Y on NM_018368.4) | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.69); catalogued as rs762697760, COSV65297127; called by muse, mutect2, varscan2
- LRFN5 | c.1735C>A p.Q579K | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as COSV53269343; called by muse, mutect2
- LRIF1 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV63898121; called by muse, mutect2, varscan2
- LRRC14B | c.1441G>T p.D481Y | Missense Mutation (SNP) | VAF 34/289 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57256454, COSV57257703; called by muse, mutect2, varscan2
- LTA4H | c.1322A>G p.N441S | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs749121418, COSV57382394; called by muse, mutect2, varscan2
- LYST | c.5707G>C p.D1903H | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.406); catalogued as COSV67711449; called by muse, mutect2
- MACROD1 | c.390G>C p.E130D | Missense Mutation (SNP) | VAF 55/399 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV55365227; called by muse, mutect2, varscan2
- MACROD2 | c.595G>T p.V199F | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.595); catalogued as COSV54027769; called by muse, mutect2, varscan2
- MANSC1 | c.1031C>G p.S344* | Nonsense Mutation (SNP) | VAF 27/256 reads (11%) | catalogued as COSV67111335; called by muse, mutect2, varscan2
- MB21D2 | c.951C>G p.I317M | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV66665253; called by muse, mutect2, varscan2
- MCF2L2 | c.487-1G>T p.X163_splice | Splice Site (SNP) | VAF 41/206 reads (20%) | catalogued as COSV100191469, COSV61058938; called by muse, mutect2, varscan2
- MED12L | c.2341C>G p.P781A | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as COSV56385730, COSV56390740; called by muse, mutect2, varscan2
- MED13 | c.5309A>G p.K1770R | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.992); catalogued as rs773229443, COSV67265937; called by muse, mutect2, varscan2
- METTL25 | c.1525G>C p.D509H | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV50260890; called by muse, mutect2
- MICAL2 | c.421G>A p.G141R | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56323887; called by muse, mutect2
- MIOS | c.2246C>T p.S749L | Missense Mutation (SNP) | VAF 17/347 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.023); catalogued as COSV60770002; called by muse, mutect2
- MPHOSPH10 | c.1897G>A p.D633N | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.768); catalogued as COSV54916036; called by muse, mutect2, varscan2
- MUC16 | c.37943C>T p.P12648L | Missense Mutation (SNP) | VAF 80/550 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.038); catalogued as rs746260347, COSV67482344; called by muse, mutect2, varscan2
- MUC17 | c.2666C>T p.P889L | Missense Mutation (SNP) | VAF 126/1416 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.584); catalogued as COSV60298538; called by muse, mutect2
- MYH15 | c.2171G>C p.R724P | Missense Mutation (SNP) | VAF 69/298 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs912664365, COSV56316388; called by muse, mutect2, varscan2
- N6AMT1 | c.292C>G p.Q98E | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV58135459; called by muse, mutect2, varscan2
- NAV3 | c.1432G>C p.V478L | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV57101772; called by muse, mutect2, varscan2
- NEK8 | c.1185C>G p.H395Q | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV52047563; called by muse, mutect2, varscan2
- NLN | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV66766768; called by muse, mutect2, varscan2
- NR1H3 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.024); catalogued as COSV68008719; called by muse, mutect2
- NRG3 | c.1808C>T p.S603L (on ENST00000404547 / NM_001370084.1; = p.S579L on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/348 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV64559951; called by muse, mutect2, varscan2
- NT5C3A | c.616G>C p.E206Q (on ENST00000610140 / NM_001374335.1; = p.E172Q on NM_016489.13) | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54239735; called by muse, mutect2, varscan2
- OBSCN | c.4471G>C p.E1491Q | Missense Mutation (SNP) | VAF 27/247 reads (11%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.926); catalogued as COSV52808935; called by muse, mutect2, varscan2
- OGT | c.1597G>C p.D533H | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.81); catalogued as COSV65482095; called by muse, mutect2, varscan2
- OR11A1 | c.487C>A p.L163M | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.781); catalogued as COSV65821288; called by muse, mutect2, varscan2
- OR2T33 | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 11/80 reads (14%) | catalogued as COSV58816981, COSV58817423; called by muse, mutect2, varscan2
- OR2T4 | c.28C>A p.H10N | Missense Mutation (SNP) | VAF 83/182 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as COSV63544772; called by muse, mutect2, varscan2
- OR5D18 | c.827C>G p.S276C | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as COSV61738181; called by muse, mutect2, varscan2
- OR5H2 | c.643A>G p.T215A | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV62351516; called by muse, mutect2, varscan2
- OR6C6 | c.167C>A p.P56Q | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as COSV64456060; called by muse, mutect2, varscan2
- OR7D2 | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.045); catalogued as COSV60140763; called by muse, varscan2
- OR8G5 | c.487A>G p.M163V | Missense Mutation (SNP) | VAF 58/304 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as COSV100422570; called by muse, mutect2, varscan2
- OR8K5 | c.535T>A p.C179S | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV57890342; called by muse, mutect2, varscan2
- ORMDL2 | c.421C>G p.Q141E | Missense Mutation (SNP) | VAF 59/293 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV54479081; called by muse, mutect2, varscan2
- OXGR1 | c.575T>G p.L192R | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV53658235; called by muse, mutect2, varscan2
- PAIP1 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as rs140543083; called by muse, mutect2, varscan2
- PAN3 | c.1915C>T p.R639* | Nonsense Mutation (SNP) | VAF 41/337 reads (12%) | catalogued as COSV56703219; called by muse, mutect2, varscan2
- PANX1 | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 23/87 reads (26%) | catalogued as COSV57134664; called by muse, mutect2, varscan2
- PATJ | c.2638C>G p.Q880E | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV57168634; called by muse, mutect2, varscan2
- PCDHA10 | c.1240C>A p.R414S | Missense Mutation (SNP) | VAF 91/587 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as rs782208845, COSV56532873; called by muse, mutect2, varscan2
- PCDHB14 | c.1336G>C p.D446H | Missense Mutation (SNP) | VAF 94/574 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53390230, COSV53390704; called by muse, mutect2, varscan2
- PCDHB15 | c.1435G>T p.D479Y | Missense Mutation (SNP) | VAF 72/390 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51223252; called by muse, mutect2, varscan2
- PCDHGA1 | c.966G>T p.Q322H | Missense Mutation (SNP) | VAF 44/238 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.076); catalogued as rs1232539322, COSV65298449; called by muse, mutect2, varscan2
- PCDHGA4 | c.1753G>T p.D585Y | Missense Mutation (SNP) | VAF 85/564 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV54002611; called by muse, mutect2, varscan2
- PCDHGB2 | c.1348C>A p.P450T | Missense Mutation (SNP) | VAF 73/414 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54002631; called by muse, mutect2, varscan2
- PCNX2 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 29/287 reads (10%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.056); catalogued as COSV50847601; called by muse, mutect2, varscan2
- PDE4D | c.1768G>A p.E590K (on ENST00000340635 / NM_001104631.2; = p.E454K on NM_006203.4) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV57719765; called by muse, mutect2, varscan2
- PDIA2 | c.991G>C p.E331Q | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.117); catalogued as COSV51991104; called by muse, mutect2, varscan2
- PELI1 | c.1115C>T p.S372L | Missense Mutation (SNP) | VAF 30/209 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV62730637; called by muse, mutect2, varscan2
- PHEX | c.638A>G p.K213R | Missense Mutation (SNP) | VAF 64/188 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as COSV65077722; called by muse, mutect2, varscan2
- PHTF1 | c.1709C>G p.S570C | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63368536; called by muse, mutect2, varscan2
- PLA2R1 | c.3829C>G p.H1277D | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.121); catalogued as COSV51784294; called by muse, mutect2, varscan2
- PLA2R1 | c.2789C>T p.S930L | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); catalogued as COSV51784307; called by muse, mutect2, varscan2
- PLAU | c.1232G>C p.R411T | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65641911, COSV65642316; called by muse, mutect2, varscan2
- PLCG1 | c.1765G>C p.E589Q | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as COSV54818529, COSV54821879; called by muse, mutect2, varscan2
- PLN | c.99C>G p.I33M | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as COSV62645924, COSV62646323; called by muse, mutect2, varscan2
- PNPLA8 | c.838C>G p.Q280E | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV57554068; called by muse, mutect2
- POLI | c.1145G>T p.R382L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54190991; called by muse, mutect2, varscan2
- PPIG | c.920A>T p.E307V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV53645044; called by muse, varscan2
- PPL | c.3649G>C p.E1217Q | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.528); catalogued as COSV52171037; called by muse, mutect2, varscan2
- PPWD1 | c.35G>A p.R12K | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs780829031, COSV54334874; called by muse, mutect2, varscan2
- PREX2 | c.4341G>T p.K1447N | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV55762789, COSV55791533; called by muse, mutect2, varscan2
- PRKD3 | c.122C>G p.S41C | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV52216423; called by muse, mutect2, varscan2
- PRSS1 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 32/318 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.814); catalogued as COSV100298050, COSV61191308, COSV61195806; called by muse, mutect2, varscan2
- PSMC3 | c.285G>T p.E95D | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.831); catalogued as COSV54082186; called by muse, mutect2, varscan2
- PZP | c.2123T>A p.V708E | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.021); catalogued as COSV54367235; called by muse, mutect2, varscan2
- RANBP17 | c.3069G>C p.L1023F | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.103); catalogued as COSV66653317, COSV66654707, COSV66658739; called by muse, mutect2, varscan2
- RASSF10 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as COSV61754618; called by muse, mutect2, varscan2
- RBBP6 | c.4300C>G p.L1434V | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs768495546, COSV60507642; called by muse, mutect2, varscan2
- RBM12 | c.1849C>T p.H617Y | Missense Mutation (SNP) | VAF 84/553 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV58293811; called by muse, mutect2, varscan2
- RBMX | c.491G>C p.R164T | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as COSV57810723; called by muse, mutect2, varscan2
- REEP5 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54842846; called by muse, mutect2
- REG1A | c.109C>G p.P37A | Missense Mutation (SNP) | VAF 84/500 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV52070894; called by muse, mutect2, varscan2
- RSPRY1 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.276); catalogued as COSV68028272; called by muse, mutect2, varscan2
- RTL8C | c.106G>C p.D36H | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs773050730, COSV57060364; called by muse, mutect2, varscan2
- RTTN | c.2225A>C p.K742T | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV55349581; called by muse, mutect2, varscan2
- RYR2 | c.9508T>C p.F3170L | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as rs771377754, COSV63703934; called by muse, mutect2, varscan2
- S1PR1 | c.668G>A p.R223K | Missense Mutation (SNP) | VAF 56/255 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.633); catalogued as COSV59512580, COSV59514065; called by muse, mutect2, varscan2
- SAE1 | c.833A>G p.D278G | Missense Mutation (SNP) | VAF 60/308 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV54297697; called by muse, varscan2
- SCPEP1 | c.1261C>G p.L421V | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV51855195; called by muse, mutect2, varscan2
- SDF4 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 57/538 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as rs1557514131, COSV55420749; called by muse, mutect2, varscan2
- SEC23IP | c.1634C>T p.P545L | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776226090, COSV64832536; called by muse, mutect2, varscan2
- SETBP1 | c.2684A>G p.D895G | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV56331847; called by muse, mutect2, varscan2
- SEZ6L | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs769535333, COSV50660077, COSV50664790; called by muse, mutect2, varscan2
- SH3GLB1 | c.818C>G p.S273* | Nonsense Mutation (SNP) | VAF 18/171 reads (11%) | catalogued as COSV65280618; called by muse, varscan2
- SHANK3 | c.1567A>G p.M523V | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.338); catalogued as COSV53189517, COSV53189723; called by muse, mutect2
- SHCBP1 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.77); catalogued as COSV57649458; called by muse, mutect2, varscan2
- SIPA1L1 | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 71/234 reads (30%) | SIFT tolerated (0.79); PolyPhen benign (0.074); catalogued as COSV62172439; called by muse, mutect2, varscan2
- SLC16A14 | c.230C>G p.S77C | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54620444; called by muse, mutect2
- SLC17A6 | c.1684G>T p.E562* | Nonsense Mutation (SNP) | VAF 16/78 reads (21%) | catalogued as COSV54134234, COSV54139499; called by muse, mutect2, varscan2
- SLC17A8 | c.1390T>A p.C464S | Missense Mutation (SNP) | VAF 43/297 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.74); catalogued as COSV60125666; called by muse, mutect2, varscan2
- SLC30A6 | c.925G>T p.E309* | Nonsense Mutation (SNP) | VAF 25/127 reads (20%) | catalogued as COSV50873681; called by muse, mutect2, varscan2
- SLC5A3 | c.389C>G p.S130C | Missense Mutation (SNP) | VAF 73/447 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62972309; called by muse, mutect2, varscan2
- SLC6A19 | c.1352del p.P451Rfs*25 | Frame Shift Del (DEL) | VAF 14/108 reads (13%) | catalogued as COSV58673399; called by mutect2, pindel, varscan2
- SLC9B2 | c.463C>A p.L155I | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.373); catalogued as COSV60021159; called by muse, mutect2, varscan2
- SLITRK2 | c.73G>C p.A25P | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.107); catalogued as COSV59427748, COSV99045888; called by muse, mutect2, varscan2
- SLITRK5 | c.2753G>T p.S918I | Missense Mutation (SNP) | VAF 74/421 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV61524958; called by muse, mutect2, varscan2
- SLTM | c.2483G>C p.R828T | Missense Mutation (SNP) | VAF 54/241 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65849904; called by muse, mutect2, varscan2
- SMAD9 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.354); catalogued as COSV63205930; called by muse, mutect2, varscan2
- SNIP1 | c.1139A>G p.D380G | Missense Mutation (SNP) | VAF 56/252 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV56167828; called by muse, mutect2, varscan2
- SNX13 | c.910G>C p.E304Q | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.671); catalogued as COSV68067116; called by muse, mutect2, varscan2
- SOGA3 | c.1479G>A p.M493I | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs1305746769, COSV100847008; called by muse, mutect2, varscan2
- SORCS3 | c.2201G>A p.R734Q | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.072); catalogued as rs750729533, COSV63793638; called by muse, mutect2, varscan2
- SPRED1 | c.71G>C p.R24P | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54438109, COSV54438678; called by muse, mutect2, varscan2
- SPRED1 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 8/234 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54438119; called by muse, mutect2
- SRGAP2 | c.2105C>G p.P702R (on ENST00000624873 / NM_001170637.4; = p.P703R on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV55341261, COSV99832606; called by muse, mutect2
- SSC4D | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs763984422, COSV51883596; called by muse, mutect2
- SSU72 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs766226081, COSV52218371; called by muse, mutect2, varscan2
- ST3GAL5 | c.279C>A p.D93E | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.785); catalogued as COSV60386619; called by muse, mutect2, varscan2
- STARD8 | c.595G>T p.E199* | Nonsense Mutation (SNP) | VAF 17/64 reads (27%) | catalogued as COSV52930384; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3122G>T p.R1041L | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as COSV59135308, COSV59138877; called by muse, mutect2, varscan2
- STRAP | c.399A>C p.E133D | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV50309005; called by muse, mutect2, varscan2
- SYCP2 | c.4069G>C p.E1357Q | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as rs1157720406, COSV62768361, COSV62771066; called by muse, mutect2, varscan2
- SYNDIG1L | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 130/401 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV59048141; called by muse, mutect2, varscan2
- TAOK3 | c.98G>C p.G33A | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66827171; called by muse, mutect2, varscan2
- TASOR2 | c.7088G>A p.R2363Q | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs1018521501, COSV60168906; called by muse, mutect2, varscan2
- TCERG1 | c.2074C>T p.P692S | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.044); catalogued as COSV57040267; called by muse, mutect2, varscan2
- TENM2 | c.3127G>T p.A1043S (on ENST00000518659 / NM_001122679.2; = p.A811S on NM_001080428.3) | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV69137691; called by muse, mutect2, varscan2
- TEX2 | c.1646G>T p.G549V | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51984284; called by muse, mutect2, varscan2
- TFAP2D | c.40-1G>C p.X14_splice | Splice Site (SNP) | VAF 30/186 reads (16%) | catalogued as COSV50409607, COSV50440416; called by muse, mutect2, varscan2
- THEMIS | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV64073110; called by muse, mutect2, varscan2
- TIGD3 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.025); catalogued as COSV52890762; called by muse, mutect2, varscan2
- TNRC18 | c.7351C>A p.P2451T | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV60308857, COSV60309876; called by muse, mutect2, varscan2
- TRHDE | c.1417G>T p.G473C | Missense Mutation (SNP) | VAF 48/343 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53858061; called by muse, varscan2
- TRIM49 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV61671541; called by muse, mutect2, varscan2
- TRPV6 | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 114/299 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.134); catalogued as COSV63893006; called by muse, mutect2, varscan2
- TTN | c.14293G>C p.E4765Q (on ENST00000591111; = p.E3838Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/181 reads (14%) | PolyPhen benign (0.068); catalogued as COSV100620444, COSV60243624; called by muse, mutect2, varscan2
- TTN | c.13508G>T p.G4503V (on ENST00000591111; = p.G3576V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/121 reads (26%) | PolyPhen probably damaging (1); catalogued as COSV60243631; called by muse, mutect2, varscan2
- UGT8 | c.916A>G p.N306D | Missense Mutation (SNP) | VAF 11/198 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV60419857; called by muse, mutect2
- USH1C | c.242G>T p.R81L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as COSV50027733; called by muse, mutect2, varscan2
- VAV2 | c.904G>A p.A302T (on ENST00000371850 / NM_001134398.2; = p.A297T on NM_003371.4) | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.999); catalogued as COSV64084138; called by muse, mutect2, varscan2
- VCPIP1 | c.874A>G p.I292V | Missense Mutation (SNP) | VAF 39/260 reads (15%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.981); catalogued as rs766667829, COSV60049492; called by muse, mutect2, varscan2
- VIM | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56404970, COSV56407110; called by muse, mutect2, varscan2
- WASF3 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 56/249 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV58969673; called by muse, varscan2
- WDR86 | c.408C>A p.H136Q | Missense Mutation (SNP) | VAF 57/107 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57842622; called by muse, mutect2, varscan2
- WFDC8 | c.689C>G p.S230* | Nonsense Mutation (SNP) | VAF 48/270 reads (18%) | catalogued as COSV51491186; called by muse, mutect2, varscan2
- WWC2 | c.1370G>C p.S457T | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66715607; called by muse, mutect2, varscan2
- ZBTB16 | c.1883C>T p.S628L | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs767860341, COSV60097743; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZFHX4 | c.9967C>T p.Q3323* | Nonsense Mutation (SNP) | VAF 3/21 reads (14%) | catalogued as COSV51483769; called by muse, mutect2
- ZFYVE26 | c.6331G>C p.E2111Q | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV61331939; called by muse, mutect2, varscan2
- ZIC4 | c.147G>T p.E49D | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV67173402; called by muse, varscan2
- ZNF175 | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 34/241 reads (14%) | catalogued as COSV51797488; called by muse, mutect2, varscan2
- ZNF407 | c.3617C>A p.S1206Y | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.276); catalogued as COSV55264162; called by muse, mutect2, varscan2
- ZNF479 | c.491A>T p.K164I | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV58641951; called by muse, mutect2, varscan2
- ZNF560 | c.1835G>T p.R612L | Missense Mutation (SNP) | VAF 35/272 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.104); catalogued as COSV56870377; called by muse, mutect2, varscan2
- ZNF578 | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 35/285 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.953); catalogued as COSV69737238; called by muse, mutect2, varscan2
- ZNF578 | c.1403C>G p.S468* | Nonsense Mutation (SNP) | VAF 13/100 reads (13%) | catalogued as rs1423205723, COSV101405047, COSV69737241; called by muse, mutect2, varscan2
- ZNF793 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.482); catalogued as COSV71324972; called by muse, mutect2, varscan2
- ZNF81 | c.683C>T p.T228I | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV58577724; called by muse, mutect2, varscan2
- ZNF862 | c.524C>T p.S175L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as COSV56225352; called by muse, mutect2, varscan2
- ZSCAN1 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 48/616 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV56607080; called by muse, mutect2
- CASP1 | c.1016_1017del p.S339Lfs*16 (on ENST00000436863 / NM_033292.4; = p.S318Lfs*16 on NM_001223.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 17/136 reads (13%) | called by mutect2, pindel, varscan2
- ICMT | c.449_450insT p.W150Cfs*43 | Frame Shift Ins (INS) | VAF 61/314 reads (19%) | called by mutect2, pindel*, varscan2
- INCENP | c.1451del p.P484Qfs*23 | Frame Shift Del (DEL) | VAF 20/102 reads (20%) | called by mutect2, pindel, varscan2
- NOCT | c.1218_1239del p.S407Tfs*4 | Frame Shift Del (DEL) | VAF 34/253 reads (13%) | called by mutect2, pindel
- OR11L1 | c.585_588delinsTTAAT p.E196* | Nonsense Mutation (INS) | VAF 34/180 reads (19%) | called by pindel, varscan2*
- PARD3 | c.2902del p.D968Ifs*11 | Frame Shift Del (DEL) | VAF 20/135 reads (15%) | called by mutect2, pindel, varscan2
- PCDHGB2 | c.1793C>G p.S598* | Nonsense Mutation (SNP) | VAF 8/190 reads (4%) | called by muse, mutect2
- RANBP17 | c.1491_1494del p.Y497* | Frame Shift Del (DEL) | VAF 35/191 reads (18%) | called by mutect2, pindel, varscan2
- SUCLA2 | c.454dup p.C152Lfs*8 | Frame Shift Ins (INS) | VAF 14/114 reads (12%) | called by mutect2, pindel, varscan2
- VN1R5 | c.397A>G p.I133V | Missense Mutation (SNP) | VAF 83/227 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- ABCC1 | c.267C>T p.L89= | Silent (SNP) | VAF 34/451 reads (8%) | catalogued as COSV100580259, COSV60691305; called by muse, mutect2
- ACSM4 | c.723C>T p.H241= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV68068849; called by muse, varscan2
- ADGRF4 | c.1608C>A p.I536= | Silent (SNP) | VAF 55/271 reads (20%) | catalogued as COSV51955668, COSV51957272; called by muse, mutect2, varscan2
- ANAPC7 | c.348G>T p.V116= | Silent (SNP) | VAF 31/183 reads (17%) | catalogued as COSV101484814, COSV71443979; called by muse, mutect2, varscan2
- ANKRD44 | c.2256G>A p.L752= | Silent (SNP) | VAF 61/392 reads (16%) | catalogued as rs768639873, COSV56562047; called by muse, mutect2, varscan2
- BRAF | c.477C>G p.V159= | Silent (SNP) | VAF 65/255 reads (25%) | catalogued as COSV56306747, COSV99956954; called by muse, mutect2, varscan2
- C1QTNF7 | c.99C>T p.I33= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as COSV54854893; called by muse, mutect2, varscan2
- CC2D1B | c.2001G>A p.L667= | Silent (SNP) | VAF 47/322 reads (15%) | catalogued as COSV52562061; called by muse, mutect2, varscan2
- CENPE | c.7635G>A p.L2545= | Silent (SNP) | VAF 35/215 reads (16%) | catalogued as COSV54382312; called by muse, mutect2, varscan2
- CLEC14A | c.603C>A p.A201= | Silent (SNP) | VAF 45/320 reads (14%) | catalogued as COSV60562357, COSV60563829; called by muse, mutect2, varscan2
- CNOT9 | c.126A>T p.L42= | Silent (SNP) | VAF 20/125 reads (16%) | catalogued as COSV55301241; called by muse, mutect2, varscan2
- CPSF1 | c.1698C>T p.D566= | Silent (SNP) | VAF 55/660 reads (8%) | catalogued as rs782612493, COSV62941774; called by muse, mutect2
- CXCL12 | c.48C>G p.L16= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV59108855; called by muse, mutect2
- CYP17A1 | c.492C>T p.S164= | Silent (SNP) | VAF 31/202 reads (15%) | catalogued as COSV64005064; called by muse, mutect2, varscan2
- DBX2 | c.930A>T p.P310= | Silent (SNP) | VAF 24/150 reads (16%) | catalogued as rs748699581, COSV60339016; called by muse, mutect2, varscan2
- DDC | c.795C>T p.D265= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs1332421479, COSV63566855; called by muse, mutect2, varscan2
- DDX60 | c.2016G>A p.V672= | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as COSV67098361; called by muse, mutect2, varscan2
- DOP1B | c.660G>T p.L220= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as COSV67695054; called by muse, mutect2
- EFR3A | c.2193G>A p.L731= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as rs1251728395, COSV54460686; called by muse, mutect2, varscan2
- ENPP2 | c.1629C>T p.T543= (on ENST00000075322 / NM_001040092.3; = p.T595= on NM_006209.5) | Silent (SNP) | VAF 89/513 reads (17%) | catalogued as COSV50028653; called by muse, mutect2, varscan2
- FAM171B | c.1194C>A p.L398= | Silent (SNP) | VAF 68/372 reads (18%) | catalogued as COSV59006681; called by muse, mutect2, varscan2
- FAM83C | c.567C>G p.L189= | Silent (SNP) | VAF 84/321 reads (26%) | catalogued as COSV65583984; called by muse, mutect2, varscan2
- FAT4 | c.3999C>T p.L1333= | Silent (SNP) | VAF 18/246 reads (7%) | catalogued as rs761822656, COSV67895515; called by muse, mutect2
- FBXO32 | c.99C>T p.F33= | Silent (SNP) | VAF 18/156 reads (12%) | catalogued as rs947647969, COSV71552316; called by muse, mutect2, varscan2
- FIGN | c.492A>T p.S164= | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as COSV60770113; called by muse, mutect2, varscan2
- FRMD6 | c.1503G>C p.V501= (on ENST00000344768 / NM_001267046.2; = p.V493= on NM_152330.4) | Silent (SNP) | VAF 17/163 reads (10%) | catalogued as COSV61090044; called by muse, mutect2, varscan2
- GABBR1 | c.2034C>T p.Y678= | Silent (SNP) | VAF 36/166 reads (22%) | catalogued as rs758589287, COSV63541979; called by muse, mutect2, varscan2
- GLI3 | c.1194G>T p.T398= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as rs148822237, COSV101230033, COSV67892982; called by muse, mutect2
- GPR32 | c.1008G>A p.A336= | Silent (SNP) | VAF 23/274 reads (8%) | catalogued as rs761150764, COSV54515212; called by muse, mutect2
- H2BC21 | c.48G>A p.K16= | Silent (SNP) | VAF 65/382 reads (17%) | catalogued as COSV58612800; called by muse, mutect2, varscan2
- HEG1 | c.1746G>A p.E582= | Silent (SNP) | VAF 5/98 reads (5%) | catalogued as COSV100230822; called by muse, mutect2
- HMGCS1 | c.6T>G p.P2= | Silent (SNP) | VAF 26/209 reads (12%) | catalogued as COSV57291083; called by muse, mutect2, varscan2
- HSPA12A | c.579G>A p.E193= | Silent (SNP) | VAF 68/457 reads (15%) | catalogued as rs1554880266, COSV65023452; called by muse, mutect2, varscan2
- HTT | c.7971C>G p.V2657= | Silent (SNP) | VAF 26/157 reads (17%) | catalogued as COSV61866771; called by muse, mutect2, varscan2
- IGLV4-3 | c.312C>T p.D104= | Silent (SNP) | VAF 26/133 reads (20%) | catalogued as rs371756657; called by muse, mutect2
- IL21 | c.43C>T p.L15= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as COSV52646789; called by muse, mutect2
- ITGA5 | c.2376C>T p.V792= | Silent (SNP) | VAF 45/312 reads (14%) | catalogued as COSV53219791; called by muse, mutect2, varscan2
- ITSN2 | c.888G>A p.Q296= | Silent (SNP) | VAF 31/113 reads (27%) | catalogued as COSV61951967; called by muse, mutect2, varscan2
- KCNA6 | c.1206C>T p.D402= | Silent (SNP) | VAF 28/282 reads (10%) | catalogued as rs762158886, COSV54975964; called by muse, mutect2
- KCNJ8 | c.75G>C p.P25= | Silent (SNP) | VAF 25/225 reads (11%) | catalogued as rs1487776087, COSV53715737, COSV53717620; called by muse, mutect2, varscan2
- KCNMB4 | c.532C>T p.L178= | Silent (SNP) | VAF 52/341 reads (15%) | catalogued as COSV50692491; called by muse, varscan2
- KIF5B | c.2727G>A p.K909= | Silent (SNP) | VAF 113/601 reads (19%) | catalogued as COSV56655014; called by muse, mutect2, varscan2
- KMT2A | c.8124G>A p.Q2708= | Silent (SNP) | VAF 22/109 reads (20%) | catalogued as rs1381046303, COSV63286649, COSV63290415; called by muse, mutect2, varscan2
- KSR1 | c.2439C>T p.S813= (on ENST00000644974 / NM_001367810.1; = p.S698= on NM_014238.2) | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as rs748666469, COSV52037029, COSV99260717; called by muse, mutect2, varscan2
- LAMA5 | c.6582C>T p.G2194= | Silent (SNP) | VAF 54/186 reads (29%) | catalogued as rs376826551; called by muse, varscan2
- LRRTM4 | c.246C>A p.A82= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as rs768339020, COSV69141331; called by muse, mutect2, varscan2
- MAGI1 | c.1191G>A p.K397= | Silent (SNP) | VAF 28/134 reads (21%) | catalogued as COSV58326077, COSV58338034; called by muse, varscan2
- MOGAT2 | c.301C>A p.R101= | Silent (SNP) | VAF 22/141 reads (16%) | catalogued as COSV52220919, COSV52221483; called by muse, mutect2, varscan2
- MRE11 | c.1746G>A p.Q582= | Silent (SNP) | VAF 24/546 reads (4%) | catalogued as rs778762259, COSV60578975; ClinVar: likely benign; called by muse, mutect2
- MSH5 | c.1038G>A p.L346= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as rs749495795, COSV65210736, COSV65210830; called by muse, mutect2, varscan2
- MUC17 | c.4056T>C p.S1352= | Silent (SNP) | VAF 292/796 reads (37%) | catalogued as COSV60298555; called by muse, varscan2
- NDN | c.246C>A p.A82= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV59360903; called by muse, varscan2
- NSUN2 | c.1971C>T p.I657= | Silent (SNP) | VAF 215/699 reads (31%) | catalogued as rs200618355; ClinVar: likely benign; called by muse, mutect2, varscan2
- NUDT16 | c.219G>A p.L73= | Silent (SNP) | VAF 26/185 reads (14%) | catalogued as COSV63248734; called by muse, mutect2, varscan2
- NUMA1 | c.4134G>A p.E1378= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as rs755017712, COSV61189249; called by muse, mutect2, varscan2
- NUP210L | c.2490C>T p.F830= | Silent (SNP) | VAF 37/213 reads (17%) | catalogued as rs759905528, COSV55141698; called by muse, mutect2, varscan2
- OR13G1 | c.357C>G p.R119= | Silent (SNP) | VAF 51/125 reads (41%) | catalogued as COSV62944943; called by muse, mutect2, varscan2
- OR1L4 | c.669C>A p.I223= | Silent (SNP) | VAF 115/685 reads (17%) | catalogued as rs140014211, COSV52341184; called by muse, varscan2
- OR2G3 | c.219C>T p.F73= | Silent (SNP) | VAF 78/729 reads (11%) | catalogued as COSV60682568; called by muse, mutect2, varscan2
- OR2M2 | c.141C>T p.L47= | Silent (SNP) | VAF 429/991 reads (43%) | catalogued as COSV62899084; called by muse, mutect2, varscan2
- OR5I1 | c.129G>A p.G43= | Silent (SNP) | VAF 22/117 reads (19%) | catalogued as rs929105704, COSV56888394; called by muse, mutect2, varscan2
- OR8D2 | c.864A>T p.L288= | Silent (SNP) | VAF 56/321 reads (17%) | catalogued as COSV62488827; called by muse, mutect2, varscan2
- PAPPA2 | c.1707C>A p.V569= | Silent (SNP) | VAF 22/149 reads (15%) | catalogued as COSV62777118; called by muse, mutect2, varscan2
- PCNX3 | c.975C>T p.S325= | Silent (SNP) | VAF 33/163 reads (20%) | catalogued as rs781093016, COSV58421170; called by muse, mutect2, varscan2
- PCNX3 | c.5271C>T p.S1757= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV63139428; called by muse, mutect2, varscan2
- PEG3 | c.2472C>A p.T824= | Silent (SNP) | VAF 48/265 reads (18%) | catalogued as COSV55642746; called by muse, mutect2, varscan2
- PIR | c.72C>G p.V24= | Silent (SNP) | VAF 72/245 reads (29%) | catalogued as COSV62918010; called by muse, mutect2, varscan2
- PLAAT5 | c.241T>C p.L81= | Silent (SNP) | VAF 191/957 reads (20%) | catalogued as rs1018124461, COSV57137963; called by muse, mutect2, varscan2
- PLEC | c.2418G>A p.E806= (on ENST00000322810 / NM_201380.4; = p.E696= on NM_000445.5) | Silent (SNP) | VAF 8/136 reads (6%) | catalogued as COSV59674900; called by muse, mutect2
- PPEF2 | c.588C>T p.L196= | Silent (SNP) | VAF 59/394 reads (15%) | catalogued as COSV54425085; called by muse, mutect2, varscan2
- PPM1K | c.36T>C p.S12= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV55797330; called by muse, mutect2, varscan2
- PTCHD1 | c.1854G>A p.L618= | Silent (SNP) | VAF 53/134 reads (40%) | catalogued as rs985359622, COSV65061691; called by muse, mutect2, varscan2
- PTCRA | c.6C>T p.A2= | Silent (SNP) | VAF 30/173 reads (17%) | catalogued as rs774492937, COSV58976525; called by muse, mutect2, varscan2
- PTPRM | c.4230G>T p.R1410= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV59874159; called by muse, mutect2, varscan2
- SDK1 | c.4053C>G p.L1351= | Silent (SNP) | VAF 27/216 reads (13%) | catalogued as COSV67382540; called by muse, mutect2, varscan2
- SH3GLB1 | c.979C>T p.L327= | Silent (SNP) | VAF 18/130 reads (14%) | catalogued as COSV65280630; called by muse, varscan2
- SLCO2B1 | c.1809C>T p.F603= | Silent (SNP) | VAF 60/306 reads (20%) | catalogued as COSV56937878; called by muse, mutect2, varscan2
- SLITRK1 | c.354C>T p.I118= | Silent (SNP) | VAF 31/217 reads (14%) | catalogued as COSV65676960; called by muse, mutect2, varscan2
- SSNA1 | c.141G>A p.V47= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV58808627; called by muse, mutect2, varscan2
- STARD8 | c.408G>C p.L136= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as COSV52930361; called by muse, mutect2, varscan2
- STRN | c.1728T>A p.A576= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV55750848; called by muse, mutect2
- SUN5 | c.186G>C p.L62= | Silent (SNP) | VAF 27/151 reads (18%) | catalogued as COSV50068743; called by muse, mutect2, varscan2
- TAF5L | c.1437C>T p.N479= | Silent (SNP) | VAF 28/416 reads (7%) | catalogued as rs776574322, COSV51084619, COSV51087539; called by muse, mutect2
- TBPL2 | c.513G>A p.E171= | Silent (SNP) | VAF 61/163 reads (37%) | catalogued as COSV55973288; called by muse, mutect2, varscan2
- TBXT | c.762G>C p.L254= | Silent (SNP) | VAF 64/117 reads (55%) | catalogued as COSV51619408, COSV99752156; called by muse, mutect2, varscan2
- TENM2 | c.4710C>T p.V1570= (on ENST00000518659 / NM_001122679.2; = p.V1331= on NM_001080428.3) | Silent (SNP) | VAF 60/349 reads (17%) | catalogued as COSV69137693; called by muse, mutect2, varscan2
- TGFBR3 | c.2064C>T p.F688= | Silent (SNP) | VAF 18/142 reads (13%) | catalogued as COSV53029438; called by muse, mutect2, varscan2
- THBS2 | c.876G>A p.E292= | Silent (SNP) | VAF 70/467 reads (15%) | catalogued as COSV64681204, COSV64682786; called by muse, mutect2, varscan2
- THNSL2 | c.528C>A p.L176= | Silent (SNP) | VAF 22/109 reads (20%) | catalogued as COSV59084151; called by muse, mutect2, varscan2
- TMIGD3 | c.591C>T p.C197= (on ENST00000369717 / NM_001081976.2; = p.C278= on NM_020683.7) | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV63163676; called by muse, mutect2, varscan2
- TMPRSS4 | c.111C>T p.I37= | Silent (SNP) | VAF 40/202 reads (20%) | catalogued as COSV71109940; called by muse, mutect2, varscan2
- TPP2 | c.3357C>T p.T1119= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as COSV65754141; called by muse, mutect2, varscan2
- TSPAN15 | c.198C>T p.L66= | Silent (SNP) | VAF 29/161 reads (18%) | catalogued as rs1314276513, COSV64782611; called by muse, mutect2, varscan2
- TXLNA | c.978C>G p.V326= | Silent (SNP) | VAF 27/227 reads (12%) | catalogued as COSV65314999; called by muse, mutect2, varscan2
- UBR2 | c.3606T>C p.D1202= | Silent (SNP) | VAF 31/147 reads (21%) | catalogued as COSV65751777; called by muse, mutect2, varscan2
- URM1 | c.192G>A p.R64= | Silent (SNP) | VAF 84/255 reads (33%) | catalogued as rs372448639; called by muse, mutect2, varscan2
- WNT7A | c.36C>G p.L12= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as COSV53201220; called by muse, mutect2, varscan2
- ZGRF1 | c.4608T>C p.C1536= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV58343029; called by muse, mutect2
- ZNF570 | c.519G>A p.Q173= | Silent (SNP) | VAF 70/327 reads (21%) | catalogued as COSV57580287; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849292 G>C | 5'Flank (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- CALCR | c.51+2978C>A | Intron (SNP) | VAF 21/106 reads (20%) | catalogued as COSV64005791, COSV64008954; called by muse, mutect2, varscan2
- CPLANE1 | c.*2497C>A | 3'UTR (SNP) | VAF 31/251 reads (12%) | catalogued as COSV57069370; called by muse, mutect2, varscan2
- EHMT2 | chr6:31901121 A>G | 5'Flank (SNP) | VAF 29/184 reads (16%) | catalogued as COSV64994070; called by muse, mutect2, varscan2
- FMN1 | c.2044-1908G>C | Intron (SNP) | VAF 15/77 reads (19%) | catalogued as COSV100568636, COSV57929908; called by muse, mutect2, varscan2
- GPR153 | c.-1C>T | 5'UTR (SNP) | VAF 16/67 reads (24%) | catalogued as COSV64938352; called by muse, mutect2
- GRM1 | c.2661-7272C>A | Intron (SNP) | VAF 20/66 reads (30%) | catalogued as COSV51202557, COSV99268134; called by muse, mutect2, varscan2
- IPO7 | c.1425+169C>T | Intron (SNP) | VAF 19/100 reads (19%) | catalogued as COSV100797834; called by muse, mutect2, varscan2
- LGALS8 | c.549+201T>C | Intron (SNP) | VAF 132/233 reads (57%) | catalogued as COSV99436647; called by muse, mutect2, varscan2
- LINC01565 | n.1274C>G | RNA (SNP) | VAF 36/215 reads (17%) | called by muse, varscan2
- MOCS2 | c.-120C>T | 5'UTR (SNP) | VAF 20/115 reads (17%) | catalogued as rs1235413038, COSV100799000, COSV63741335; called by muse, mutect2, varscan2
- NXF5 | n.788G>A | RNA (SNP) | VAF 34/145 reads (23%) | catalogued as rs1191714396, COSV53790325; called by muse, mutect2, varscan2
- RTCA | c.800-3937C>T | Intron (SNP) | VAF 13/135 reads (10%) | catalogued as rs559168796, COSV53121756; called by muse, mutect2
- TTN | c.10361-5334G>A | Intron (SNP) | VAF 26/126 reads (21%) | catalogued as rs753816084, COSV60243639; called by muse, mutect2, varscan2
- UBTFL2 | n.187T>A | RNA (SNP) | VAF 14/125 reads (11%) | catalogued as rs766003110; called by muse, mutect2, varscan2
- Y_RNA | chr7:75516151 C>A | 5'Flank (SNP) | VAF 59/229 reads (26%) | called by muse, mutect2, varscan2
